Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A3YN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A3YN-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number : --

ICD-O-3

melanoma, NOS 8720/3

Site:

CRCF - lymph node, inguinal C77
PATH - lymph node, inguinal C77.4

6-6-12
RD

Surgical Pathology Report

Accession #:

Diagnosis:

Lymph nodes, left superficial inguinal, dissection

-Metastatic melanoma involving 1 out of 14 lymph nodes, with the largest

diameter measuring approximately 3.5 cm and no evidence of capsular involvement

or extracapsular extension (1/14)

-Block A13 will be sent for BRAF testing

Clinical History:

-year-old with lymphadenopathy (per "

Lymph node, left

inguinal, core biopsy Metastatic melanoma).

Gross Description:

Received is one appropriately labeled container, additionally labeled "left

superficial inguinal node dissection, short stitch/superior, long

stitch/lateral." It holds a fragment of yellow lobulated fat, roughly 13.5 cm

from superior to inferior x 5.5 cm from lateral to medial x 3.5 cm in thickness.

On one surface there is a 5.3 x 0.4 cm tan ellipse of skin.

Within the fragment

immediately inferior and medial to the skin ellipse there is a 3.5 cm in

greatest dimension lymph node which on section has a mottled tan/brown to

tan/pink cut surface. A representative section of this lymph node is submitted

to Tissue Procurement. Further sectioning reveals additional lymph nodes. The

specimen is submitted moving from superior towards inferior in the following

[page 2 of 2]
blocks:

- A1 - one lymph node, bisected
- A2-A3 - one lymph node, serially sectioned
- A4 - one lymph node, bisected
- A5 - one lymph node, trisected
- A6 - four lymph nodes
- A7,A8 - one lymph node, trisected
- A9,A10 - one lymph node, trisected
- A11 - two lymph nodes
- A12 - representative sections of skin and underlying soft tissue
- A13 - representative sections of largest lymph node
- A14 - representative section of vessel

Source: NCI Genomic Data Commons file 2dc41b76-0c7d-4199-a417-ab6d96bd725d (TCGA-FR-A3YN.E2BF0131-CC97-4816-A7FA-E21E3F8932D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).